Somatic mutation profile of tumor specimen ALCH-B4SJ-TTR1-A (aliquot ALCH-B4SJ-TTR1-A-3-0-D-A85H-36) from ALCHEMIST case ALCH-B4SJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.8 years (27,331 days).
Specimen ALCH-B4SJ-TTR1-A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73c589d4-3b7d-492b-a365-2658c76392d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4SJ-NB1-A (Blood Derived Normal), aliquot ALCH-B4SJ-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db8f002e-07d6-453b-94ab-021a842497e8

The open-access MAF lists 64 somatic variants for this specimen: 42 protein-altering or splice-affecting, 16 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 16, Nonsense Mutation 5, Frame Shift Del 3, Intron 3, Splice Site 1, In Frame Del 1, 5'Flank 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 3498/3944 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 309/362 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs863224683, CM016206, COSV52686543, COSV52692226, COSV99368721; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS16 | c.3509C>T p.S1170L | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs762838325, COSV56985201; called by muse, mutect2, varscan2
- BYSL | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 41/298 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs750647786; called by muse, mutect2, varscan2
- CAPN15 | c.1709G>T p.R570L | Missense Mutation (SNP) | VAF 102/325 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as rs548702059; called by muse, mutect2, varscan2
- DGKB | c.374C>A p.A125E | Missense Mutation (SNP) | VAF 47/270 reads (17%) | SIFT tolerated (0.87); PolyPhen benign (0.024); catalogued as rs1378719804, COSV51821159; called by muse, mutect2, varscan2
- DRC3 | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 66/249 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs760498955; called by muse, mutect2, varscan2
- GLG1 | c.1369C>T p.R457* | Nonsense Mutation (SNP) | VAF 144/217 reads (66%) | catalogued as COSV52664415; called by muse, mutect2, varscan2
- GPRASP1 | c.1483C>G p.Q495E | Missense Mutation (SNP) | VAF 62/215 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64355184; called by muse, mutect2, varscan2
- HELQ | c.2383C>T p.L795F | Missense Mutation (SNP) | VAF 63/207 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV55028285, COSV99787331; called by muse, mutect2, varscan2
- MAS1 | c.657G>A p.W219* | Nonsense Mutation (SNP) | VAF 13/246 reads (5%) | catalogued as rs1171926339, COSV53120637; called by muse, mutect2
- MRAP2 | c.44C>A p.S15* | Nonsense Mutation (SNP) | VAF 103/137 reads (75%) | catalogued as COSV57634132, COSV57634287; called by muse, mutect2, varscan2
- OR2T2 | c.189G>T p.L63F | Missense Mutation (SNP) | VAF 267/1254 reads (21%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.998); catalogued as rs755379689; called by muse, mutect2, varscan2
- PHRF1 | c.2833G>A p.D945N (on ENST00000264555 / NM_001286581.2; = p.D944N on NM_020901.4) | Missense Mutation (SNP) | VAF 44/240 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.461); catalogued as rs1168153002; called by muse, mutect2, varscan2
- TRAF7 | c.2010C>A p.C670* | Nonsense Mutation (SNP) | VAF 80/403 reads (20%) | catalogued as rs1283228225, COSV100398997, COSV58217446; called by muse, mutect2, varscan2
- WIPF3 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.5); catalogued as rs1171511127; called by muse, varscan2
- AHNAK2 | c.14927A>G p.D4976G | Missense Mutation (SNP) | VAF 151/230 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- ASTN1 | c.1548G>C p.Q516H | Missense Mutation (SNP) | VAF 38/314 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- ATRAID | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 177/223 reads (79%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- C10orf90 | c.701_702delinsG p.F234Cfs*34 | Frame Shift Del (DEL) | VAF 48/199 reads (24%) | called by pindel, varscan2*
- CDK14 | c.37A>T p.I13F | Missense Mutation (SNP) | VAF 58/244 reads (24%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- CERKL | c.1211+1G>A p.X404_splice (on ENST00000339098 / NM_001030311.2; = p.X378_splice on NM_201548.5) | Splice Site (SNP) | VAF 54/184 reads (29%) | called by muse, mutect2, varscan2
- F5 | c.2584C>T p.H862Y | Missense Mutation (SNP) | VAF 71/305 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GABRA5 | c.1340C>T p.T447M | Missense Mutation (SNP) | VAF 81/283 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GAREM2 | c.2400G>A p.W800* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | called by muse, mutect2, varscan2
- GUCY2D | c.2653G>T p.D885Y | Missense Mutation (SNP) | VAF 548/620 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMA4 | c.273_281del p.L92_G94del | In Frame Del (DEL) | VAF 126/409 reads (31%) | called by mutect2, pindel, varscan2
- LARP7 | c.1121T>C p.I374T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- LYN | c.1354G>A p.V452M | Missense Mutation (SNP) | VAF 81/123 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MKI67 | c.1353A>T p.Q451H | Missense Mutation (SNP) | VAF 85/116 reads (73%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MYO15B | c.3309A>C p.Q1103H | Missense Mutation (SNP) | VAF 308/363 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCAM1 | c.1582C>A p.Q528K (on ENST00000316851 / NM_181351.5; = p.Q518K on NM_000615.7) | Missense Mutation (SNP) | VAF 147/183 reads (80%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PASD1 | c.1767C>A p.N589K | Missense Mutation (SNP) | VAF 22/718 reads (3%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.556); called by muse, mutect2
- PHKB | c.1144C>G p.P382A | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2
- PIEZO2 | c.1015A>T p.I339F | Missense Mutation (SNP) | VAF 16/404 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.054); called by muse, mutect2
- STK39 | c.878T>G p.L293W | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- STK39 | c.872_875del p.P291Lfs*6 | Frame Shift Del (DEL) | VAF 26/104 reads (25%) | called by pindel, varscan2
- TOPORS | c.2470C>G p.H824D | Missense Mutation (SNP) | VAF 48/229 reads (21%) | SIFT tolerated (0.81); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TRIM46 | c.294G>C p.K98N | Missense Mutation (SNP) | VAF 63/402 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- USH2A | c.11355del p.P3786Lfs*6 | Frame Shift Del (DEL) | VAF 199/566 reads (35%) | called by mutect2, pindel, varscan2
- ZDHHC15 | c.209G>T p.W70L | Missense Mutation (SNP) | VAF 69/278 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF541 | c.1325G>C p.R442P | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCC8 | c.702C>T p.N234= | Silent (SNP) | VAF 171/644 reads (27%) | catalogued as rs758289249; called by muse, mutect2, varscan2
- APOB | c.3876C>T p.N1292= | Silent (SNP) | VAF 98/231 reads (42%) | called by muse, mutect2, varscan2
- GPR101 | c.1107A>T p.A369= | Silent (SNP) | VAF 9/176 reads (5%) | called by muse, mutect2
- IFT52 | c.549T>A p.V183= | Silent (SNP) | VAF 218/472 reads (46%) | called by muse, mutect2, varscan2
- NAPSA | c.76C>T p.L26= | Silent (SNP) | VAF 87/227 reads (38%) | called by muse, mutect2, varscan2
- NCAPD2 | c.1359G>A p.E453= | Silent (SNP) | VAF 99/325 reads (30%) | catalogued as rs200847598; called by muse, mutect2, varscan2
- PCDHB2 | c.1428C>T p.S476= | Silent (SNP) | VAF 187/932 reads (20%) | catalogued as rs1554271431, COSV50638954; called by muse, varscan2
- PCDHGA6 | c.2214G>A p.S738= | Silent (SNP) | VAF 27/551 reads (5%) | catalogued as rs1283407370; called by muse, mutect2
- POLRMT | c.636G>T p.G212= | Silent (SNP) | VAF 23/52 reads (44%) | called by mutect2, varscan2
- RANGAP1 | c.411G>A p.K137= | Silent (SNP) | VAF 71/249 reads (29%) | called by muse, mutect2, varscan2
- SH2D1A | c.114A>T p.P38= | Silent (SNP) | VAF 156/654 reads (24%) | called by muse, mutect2, varscan2
- SLC9A3 | c.1245C>T p.R415= | Silent (SNP) | VAF 267/485 reads (55%) | catalogued as rs143761751, COSV99375879; called by muse, mutect2, varscan2
- SPEN | c.9021C>A p.I3007= | Silent (SNP) | VAF 45/210 reads (21%) | catalogued as COSV101004925; called by muse, mutect2, varscan2
- THBS2 | c.18C>T p.V6= | Silent (SNP) | VAF 118/252 reads (47%) | called by muse, mutect2, varscan2
- TRGV4 | c.144C>A p.T48= | Silent (SNP) | VAF 346/928 reads (37%) | called by muse, mutect2
- UNC13B | c.12C>G p.L4= | Silent (SNP) | VAF 50/152 reads (33%) | called by muse, mutect2, varscan2
- BAP1 | c.1891-56G>A | Intron (SNP) | VAF 107/316 reads (34%) | catalogued as rs767198116; called by muse, mutect2, varscan2
- GFM1 | c.81+17_81+18del | Intron (DEL) | VAF 172/246 reads (70%) | called by pindel, varscan2
- MIR331 | n.26C>T | RNA (SNP) | VAF 242/332 reads (73%) | called by muse, mutect2, varscan2
- PHACTR3 | c.*15G>A | 3'UTR (SNP) | VAF 10/42 reads (24%) | catalogued as COSV63033827; called by muse, mutect2, varscan2
- PSMD5 | chr9:120843131 A>G | 5'Flank (SNP) | VAF 129/164 reads (79%) | catalogued as rs548237507; called by muse, mutect2, varscan2
- SYNE2 | c.11485-2665A>T | Intron (SNP) | VAF 19/495 reads (4%) | called by muse, mutect2
